Gene-level copy-number profile of tumor specimen C3N-02633-02 from CPTAC case C3N-02633, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.7 years (20,362 days).
Specimen C3N-02633-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56b35585-678c-47bd-9b6f-ab7331b1b471.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02633-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/0c091d70-b091-4218-aca8-3af09058d3c0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 3,555; copy number 2: 15,419; copy number 3: 23,922; copy number 4: 11,023; copy number 5: 4,419; copy number 6: 13; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,890,314–42,626,813, 18 genes (within-gene range 0–2): CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5.
- chr9:64,369,394–64,765,535, 14 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–2): NUTM2B.
- chr10:87,201,647–87,370,695, 6 genes: NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,331,657–202,341,980, 1 gene, copy number 7: UBE2T.

Autosomal genes at a single copy (total copy number 1): 1,219. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
